Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A3F3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A3F3-06A (Metastatic).

[page 1 of 3]
CAL PATHOLOGY REPORT

Procedures/Addenda Attached

Patient: [REDACTED]
MR: [REDACTED]
DOB/Age/Sex: [REDACTED] Age: [REDACTED]
YNHH Visit #: [REDACTED]
Submitting Physician: [REDACTED]
Other Physicians: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Accessioned: [REDACTED]
Adm-Disch Date: [REDACTED]
Reported: [REDACTED]

Clinical History and Impression:
Melanoma
year old

Specimen(s) Received:
LEFT NECK MASS

FINAL DIAGNOSIS

LEFT NECK MASS, EXCISION:

- CONSISTENT WITH METASTATIC MELANOMA IN ONE OF FIVE LYMPH NODES (1/5), WITH EXTRANODAL EXTENSION
- GREATEST DIMENSION OF LYMPH NODE WITH METASTASIS: 2.9 CM

Pathologist: [REDACTED]
* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received in formalin, labeled with the patient's name, unit number and "left neck mass" is an unoriented 4.3 x 2.3 cm tan-pink skin ellipse excised to a depth of 3.2 cm. A 1.1 x 0.9 cm dark brown, ill-defined lesion is identified on the skin surface. It is <1 mm from the closest resection margin. The entire resection margin is inked blue and the specimen is serially sectioned from one tip to the other tip to reveal a tan-brown to tan-red, ill-defined mass with a maximum depth of 2.9 cm and is ~2 cm from the deep resection margin. Gross photographs are taken. The specimen is entirely submitted sequentially in twelve cassettes with the tips from both sides submitted in cassettes #1-2.

Summary of Stains Performed and Reviewed

Count
1
1
1

The immunohistochemical profile may include the use of [REDACTED] whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the [REDACTED] it has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for the test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and internal controls stained appropriately.

Page 1 of 3

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, neck C77.0
w/ 11/13/11

Diagnostic Discrepancy		X
HPA Discrepancy		X

Reviewer Initials: [REDACTED] Date Reviewed: 11/13/11

[page 2 of 3]
Summary of Tissue Submitted for Microscopic Examination

Part 1] LEFT NECK MASS

Block Detail

# Blocks	Designation	#	Description
12	[Undes]	(12)	(No Description)

Procedures/Addenda

IMMUNOHISTOCHEMISTRY

Status: Signed Out

Pathologist:

Ordered:

Reported:

Interpretation

Immunohistochemical studies show that the tumor is positive for Melan-A and HMB45, consistent with melanoma.

MOLECULAR DIAGNOSTIC TESTS

Status: Signed Out

Pathologist:

Ordered:

Reported:

Findings (Results)

PCR-SSCP analysis of BRAF gene was performed on

BRAF gene V600E mutation was IS NOT identified.

Analytic spec: reagent (ASR) is used. This test was developed and its performance characteristics determined by the manufacturer. The test has not been cleared or approved by the U.S. Food and Drug Administration. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Interpretation

The BRAF gene encodes a protein that is a component of the RAS/MAPK signaling pathway involving the control of cell proliferation, differentiation, and apoptosis. This gene may be mutated in many types of cancer, particularly thyroid cancer. BRAF mutation (V600E) occurs in 40-60% of papillary thyroid cancer (PTC). It has been shown that such mutations are associated with a more aggressive phenotype of PTC. BRAF mutation testing of FNA specimens provides a powerful tool to preoperatively identify PTC patients at higher risk for extensive disease (extrathyroidal extension and lymph node metastases). Journal of Clinical Oncology 27:2977-2982, 2009.

BRAF V600E mutation is not detected in the specimen tested.

Source: NCI Genomic Data Commons file 7dedc06e-b92b-4320-96d2-8728e522e2b9 (TCGA-DA-A3F3.66035FA9-7600-46C5-A5F5-CBD1CC1C1AD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).